FM case AD11425 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/45336b73-03af-45dc-a9ea-8d8ef2894ddd

Female, 55.3 years: diagnosis not reported by GDC; metastasis biopsied or resected from the bladder. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Metastatic.
